Gene-level copy-number profile of tumor specimen TCGA-FD-A5BV-01A from TCGA case TCGA-FD-A5BV, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Trigone of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 47.9 years (17,501 days).
Specimen TCGA-FD-A5BV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.62464342-f170-42a1-bfc4-659b987445cf.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FD-A5BV-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b3df561b-2d27-48d3-a52e-bf76957eeacc

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 24; copy number 1: 14; copy number 2: 93; copy number 3: 8,340; copy number 4: 8,444; copy number 5: 19,023; copy number 6: 11,824; copy number 7: 9,560; copy number 8: 122; copy number 9: 667; copy number 10: 782; copy number 11: 439; copy number 12: 154; copy number 13: 154; copy number 14: 34; copy number 17: 33; copy number 19: 103.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FD-A5BV-01A-11D-A26L-01): tumor purity 0.89, ploidy 1.79, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 24 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:140,992,543–141,208,376, 3 genes: Y_RNA, RNU6-904P, RPS16P3.
- chr2:227,610,090–227,648,606, 1 gene (within-gene range 0–3): C2orf83.
- chr2:227,666,804–228,841,689, 19 genes: SCYGR5, SLC19A3, SCYGR6, SCYGR7, SCYGR8, RNA5SP121, SNRPGP8, AC073065.1, CCL20, TDGF1P2, DAW1, AC073065.2, SPHKAP, RNU6-624P, SNF8P1, AC009410.1, LINC01807, AC012070.1, RPL7L1P10.
- chr5:60,021,249–60,033,020, 1 gene: AC034234.1.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 917 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:90,958,471–106,060,524, 298 genes, copy number 11 (within-gene range 10–11) (broad region; genes not listed).
- chr8:110,334,743–124,539,458, 154 genes, copy number 12 (broad region; genes not listed).
- chr8:125,348,196–133,963,259, 116 genes, copy number 11–13 (broad region; genes not listed).
- chr11:81,821,272–82,733,864, 7 genes, copy number 13: MIR4300HG, AP002802.2, MIR4300, AP002802.1, AP000793.1, RPS28P7, FAM181B.
- chr16:24,610,209–24,827,632, 1 gene, copy number 17 (within-gene range 5–17): TNRC6A.
- chr16:24,803,451–26,729,126, 32 genes, copy number 17: AC008731.1, SLC5A11, ARHGAP17, AC133552.1, AC133552.2, LINC02175, SCML2P2, AC133552.4, LCMT1-AS1, AC133552.3, AC133552.5, LCMT1, LCMT1-AS2, RN7SL557P, AQP8, ZKSCAN2, AC008741.1, ZKSCAN2-DT, LINC02191, CYCSP39, HS3ST4, AC093516.1, AC093524.1, MIR548W, RNA5SP405, HMGN2P3, HSPE1P16, AC009158.1, AC130464.1, AC002331.1, LINC02195, AC009035.1.
- chr19:19,145,567–22,010,949, 137 genes, copy number 14–19 (within-gene range 6–19) (broad region; genes not listed).
- chr22:24,806,169–26,780,893, 63 genes, copy number 11 (within-gene range 6–11) (broad region; genes not listed).
- chr22:26,886,909–26,887,548, 1 gene, copy number 11: Z97353.1.
- chr22:29,073,035–29,168,333, 1 gene, copy number 13 (within-gene range 4–13): KREMEN1.
- chr22:29,134,014–31,348,719, 107 genes, copy number 13 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 14. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
